Gene-level copy-number profile of tumor specimen ALCH-B36Y-TTP1-A from ALCHEMIST case ALCH-B36Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,599 days).
Specimen ALCH-B36Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0dd40c0d-552d-4ad5-a1e2-d9a750abfec6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/ec319d97-e3e5-487c-a55c-eaabaee464ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 674; copy number 1: 11,606; copy number 2: 42,176; copy number 3: 3,704; copy number 4: 752; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,316,319–52,535,054, 9 genes (within-gene range 0–2): DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:21,284,672–21,419,870, 2 genes: MAP2K3, KCNJ12.
- chr22:17,734,138–19,122,454, 66 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:1,039,997–1,065,572, 1 gene, copy number 5: ABCA7.
- chr19:1,259,384–1,279,244, 3 genes, copy number 5: CIRBP, CIRBP-AS1, FAM174C.

Autosomal genes at a single copy (total copy number 1): 9,514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
